Gene-level copy-number profile of tumor specimen C3L-00927-02 from CPTAC case C3L-00927, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.4 years (27,187 days).
Specimen C3L-00927-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 558ae186-7658-45c8-8291-96b2b9870263.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00927-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/f0a062bf-700a-472f-b38c-879ae80d1646

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 710; copy number 1: 68; copy number 2: 13,201; copy number 3: 605; copy number 4: 34,802; copy number 5: 350; copy number 6: 6,249; copy number 7: 32; copy number 8: 1,032; copy number 9: 105; copy number 10: 1,223; copy number 13: 24; copy number 14: 94; copy number 15: 29; copy number 16: 1; copy number 17: 61; copy number 18: 60; copy number 22: 33; copy number 23: 34; copy number 24: 73; copy number 26: 6; copy number 27: 1; copy number 29: 30; copy number 32: 7; copy number 35: 3; copy number 38: 3; copy number 40: 8; copy number 45: 9; copy number 46: 9; copy number 47: 3; copy number 49: 6; copy number 53: 37.

Homozygous deletions (total copy number 0; autosomes only): 202 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,926,337–8,049,267, 12 genes: ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:12,378,679–12,380,265, 1 gene (within-gene range 0–2): AC087203.2.
- chr9:52,452–1,978,547, 28 genes: AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL591644.1.
- chr9:2,041,900–2,046,023, 1 gene (within-gene range 0–2): AL359076.1.
- chr9:8,314,246–15,307,360, 60 genes (within-gene range 0–2): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr9:15,464,066–16,061,663, 8 genes (within-gene range 0–2): PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P.
- chr9:19,409,009–25,089,151, 92 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,859 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–51,919,381, 15 genes, copy number 9: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1.
- chr4:52,252,820–52,551,574, 3 genes, copy number 13: AC097522.2, AC097522.1, RNU6-1252P.
- chr4:67,417,305–79,877,770, 263 genes, copy number 10–40 (broad region; genes not listed).
- chr5:58,198–2,967,955, 83 genes, copy number 9 (broad region; genes not listed).
- chr5:4,012,708–4,866,311, 7 genes, copy number 9 (within-gene range 6–9): AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1.
- chr5:6,686,325–54,415,238, 609 genes, copy number 10–22 (broad region; genes not listed).
- chr6:103,583,135–108,005,568, 60 genes, copy number 15–53: AL591387.1, R3HDM2P2, NPM1P10, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, LINC02836, Z97206.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4, SEC63, RNU6-437P, RPL23AP50, AL024507.2, AL024507.1, SNORA73, MTHFD2P3, RPL3P7.
- chr8:112,148,742–112,148,825, 1 gene, copy number 16: RNU4-37P.
- chr8:117,794,490–120,056,201, 30 genes, copy number 14–49: EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.
- chr8:120,913,065–121,380,465, 3 genes, copy number 35: AC068413.1, AC011626.1, RPL35AP19.
- chr8:125,648,327–126,008,930, 1 gene, copy number 32 (within-gene range 2–32): AC016074.2.
- chr8:125,859,721–126,292,788, 1 gene, copy number 32 (within-gene range 2–47): LINC00861.
- chr8:125,951,861–128,564,679, 38 genes, copy number 15–47: SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:139,727,725–140,458,579, 1 gene, copy number 45 (within-gene range 2–45): TRAPPC9.
- chr8:140,039,756–141,002,216, 10 genes, copy number 13–45 (within-gene range 2–45): AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A.
- chr8:140,940,562–142,917,843, 53 genes, copy number 13–23: RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2.
- chr8:143,157,914–144,314,720, 73 genes, copy number 24 (within-gene range 2–24) (broad region; genes not listed).
- chr11:10,812,074–13,387,266, 41 genes, copy number 10–14 (within-gene range 2–14): ZBED5, ZBED5-AS1, AC069360.1, LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1, GALNT18, CSNK2A3, AC023946.1, AC104031.1, MIR4299, AC131935.2, AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151.
- chr11:33,698,261–34,743,199, 26 genes, copy number 10 (within-gene range 6–10): AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1.
- chr12:19,404,045–22,437,041, 45 genes, copy number 10–14 (within-gene range 6–14): AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P.
- chr15:85,744,109–92,331,037, 159 genes, copy number 10–38 (within-gene range 8–38) (broad region; genes not listed).
- chr15:97,960,703–99,105,824, 22 genes, copy number 22–46 (within-gene range 2–46): ARRDC4, AC024651.1, LINC02251, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1.
- chr17:16,829,999–16,845,881, 2 genes, copy number 10: KRT16P2, KRT17P1.
- chr20:30,214,765–39,815,097, 293 genes, copy number 10 (broad region; genes not listed).
- chr22:18,340,145–18,719,341, 20 genes, copy number 14: GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 63. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
